Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A6C9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A6C9-06A (Metastatic).

[page 1 of 4]
Melanoma, malignant^{N6S}
8720/3
Site Parotid gland
607.9
JW 5/24/13

Operative Procedure:

Left parotidectomy, left neck dissection.

Specimen Received:

- A: Soft tissue over tumor (FS)
- B: Soft tissue over tumor #2 (FS)
- C: Left parotid; stitch superior
- D: Left neck dissection, levels 2-3; stitch marks 2A
- E: Left neck dissection, level 2B
- F: Level 4 lymph node
- G: Deep margin at facial nerve stump (FS)
- H: Parotid margin (FS)
- I: Great auricular nerve margin (FS)

Final Pathologic Diagnosis:

Parotid, left, parotidectomy:

Metastatic melanoma (1/31 lymph nodes positive (Part C), maximal dimension 2.2 cm).

Surgical margins free of malignancy.

A. Soft tissue over tumor, biopsy:

Negative for tumor.

Frozen section diagnosis confirmed.

B. Soft tissue over tumor #2, biopsy:

Negative for tumor.

Frozen section diagnosis confirmed.

C. Parotid, left, parotidectomy:

Metastatic melanoma (1/5 lymph nodes positive, maximal dimension 2.2 cm, margins clear).

D. Left neck dissection, levels 2 and 3:

Twenty lymph nodes negative for tumor (0/20).

E. Left neck dissection, level 2B:

Five lymph nodes negative for tumor (0/5).

F. Lymph node, level 4, excision:

One lymph node negative for tumor (0/1).

G. Deep margin at facial nerve stump, biopsy:

Negative for tumor.

Frozen section diagnosis confirmed.

[page 2 of 4]
H. Parotid margin, biopsy:
Negative for tumor.
Frozen section diagnosis confirmed.

I. Great auricular nerve margin, biopsy:
Negative for tumor.
Frozen section diagnosis confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Soft tissue over tumor:
No tumor identified on sections examined.
F/S TAT: 26 mins.

FSB: Soft tissue over tumor #2:
No tumor identified on sections examined.
F/S TAT: 20 mins.

FSG: Deep margin at facial stump:
No tumor identified on sections examined.

FSH: Parotid margin:
No tumor identified on sections examined.

FSI: Great auricular nerve margin: No tumor identified on sections examined.
F/S TAT: 15 mins.

Gross Description:

Received are nine formalin filled containers, all labeled with the patient's name

Part A is additionally labeled "soft tissue over tumor." Received fresh for frozen section microscopy is a portion of pink-tan irregular soft tissue measuring 0.7 x 0.2 x 0.2 cm. This is submitted in toto for frozen section microscopy. The residual tissue is now being resubmitted in cassette A1.

Part B is additionally labeled "soft tissue over tumor #2." Received fresh for frozen section microscopy is a portion of tan-yellow irregular soft tissue measuring 0.9 x 0.5 x 0.1 cm. This is submitted in toto for frozen section microscopy. The residual tissue is now being resubmitted in cassette B1.

Part C is additionally labeled "left parotid, stitch superior" and consists of a portion of yellow-tan lobulated soft tissue, having overall dimensions of 7 x 4.9 x 4 cm. The specimen is received with a stitch designating the superior aspect. Step sectioning reveals a 2.2 x 2 x 1.6 cm tan-white to red-brown and focally hemorrhagic, well circumscribed nodule arising within the central portion of the parotid. This comes within 0.1 cm of the inked external surface. Additionally, three intraparotid lymph nodes, grossly suspicious for metastatic

[page 3 of 4]
cancer, are found within the parotid. There is a 2 x 2 x 1.5 cm portion of skeletal muscle on the superficial aspect of the specimen. Within this muscle, a single lymph node is found measuring 0.6 cm in greatest dimension.

Representative sections are submitted as follows:

- C1 tumor to parotid bed;
- C2 tumor to superficial muscle;
- C3 additional tumor;
- C4-6 each with one intraparotid lymph node;
- C7 one lymph node bisected.

Part D is additionally labeled "left neck dissections level 2-3, stitch marks 2A" and consists of a portion of fibrofatty soft tissue, having overall dimensions of 11 x 4.5 x 2 cm. There is a stitch designating the level 2. Extensive palpation reveals eleven whole lymph nodes up to 1.5 cm in greatest dimension in the level 2 portion.

These are submitted as follows:

- D1 one lymph node bisected;
- D2 one lymph node bisected;
- D3 three whole lymph nodes;
- D4 four whole lymph nodes;
- D5 two whole lymph nodes.

Extensive palpation through the level 3 portion of the neck dissection reveals ten whole lymph nodes up to 2.1 cm in greatest dimension.

These lymph nodes are submitted as follows:

- D6 five whole lymph nodes;
- D7 two whole lymph nodes;
- D8-10 each with one lymph node bisected.

Part E is additionally labeled "left neck dissection level 2B" and consists of two portions of fibrofatty soft tissue measuring 2 and 3 cm in greatest dimension. Extensive palpation reveals seven potential whole lymph nodes.

These are submitted as follows:

- E1 four whole lymph nodes;
- E2 three whole lymph nodes.

Part F is additionally labeled "level 4 lymph node" and consists of a single lymph node measuring 1.5 cm in greatest dimension. This is bisected and submitted entirely in cassette F1.

Part G is additionally labeled "deep margin at facial nerve stump." Received fresh for frozen section microscopy is a portion of tan-yellow irregular soft tissue with reapproximated dimensions of 0.9 x 0.5 x 0.2 cm. This is submitted in toto for frozen section microscopy. The residual tissue is now being resubmitted in cassette G1.

[page 4 of 4]
Part H is additionally labeled "parotid margin." Received fresh for frozen section microscopy is a portion of pink-tan irregular soft tissue measuring 1 x 0.5 x 0.2 cm. This is submitted in toto for frozen section microscopy. The residual tissue is now being resubmitted in cassette H1.

Part I is additionally labeled "right auricular nerve margin." Received fresh for frozen section microscopy is a portion of pink-tan irregular soft tissue with reapproximated dimensions of 0.9 x 0.5 x 0.2 cm. This is submitted in toto for frozen section microscopy. The residual tissue is now being resubmitted in cassette I1.

Microscopic Description:

Histologic examination reveals an enlarged lymph node within the parotid gland. The node is expanded by a population of highly pleomorphic tumor cells with enlarged vesicular nuclei and prominent cherry-red nucleoli. The nuclei are eccentrically placed. Focal nuclear inclusions as well as multi-nucleated cells are also noted. Immunohistochemistry is preformed and the lesional cells are positive for S100 and Melan-A and negative for AE1/AE3, epithelial antigen, and HMB-45. CD45 highlights only the surrounding lymphoid tissue.

END OF REPORT

Taken: DOB: Age: Gender: M

Source: NCI Genomic Data Commons file cc558ee9-3e50-45a3-9da0-80e4d65c9e95 (TCGA-GF-A6C9.2A307856-4434-47EA-AA17-DAA48E3EA1BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).